Somatic mutation profile of tumor specimen C3N-03173-01 (aliquot CPT0186040013) from CPTAC case C3N-03173, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 64.8 years (23,662 days).
Specimen C3N-03173-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb359862-8249-48f6-8ee8-90dfe1ff27a8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03173-31 (Blood Derived Normal), aliquot CPT0187290002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/887f386e-0e68-45f5-8fb8-26338759d88c

The open-access MAF lists 50 somatic variants for this specimen: 34 protein-altering or splice-affecting, 12 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 12, RNA 2, Frame Shift Ins 2, 5'UTR 1, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 32/330 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 32/383 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ADA | c.157G>C p.D53H | Missense Mutation (SNP) | VAF 40/509 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV100866645, COSV65739954; called by muse, mutect2
- CBFA2T3 | c.1913G>A p.R638H | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs562711336; called by muse, mutect2, varscan2
- CLVS2 | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 18/312 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs766143997, COSV104390204; called by muse, mutect2
- CNTLN | c.1810C>T p.R604* | Nonsense Mutation (SNP) | VAF 20/252 reads (8%) | catalogued as rs375104473; called by muse, mutect2
- DMP1 | c.1528C>A p.Q510K | Missense Mutation (SNP) | VAF 28/388 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56819154, COSV99218567; called by muse, mutect2
- DYSF | c.1403G>A p.R468H | Missense Mutation (SNP) | VAF 43/483 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs775370021, COSV50269980; called by muse, mutect2
- HIVEP3 | c.5240G>A p.R1747Q | Missense Mutation (SNP) | VAF 30/281 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769827954, COSV56014043; called by muse, mutect2
- KIF18B | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.329); catalogued as rs781011969, COSV59271080; called by muse, mutect2, varscan2
- NDRG4 | c.643C>T p.R215W (on ENST00000570248 / NM_001378344.1; = p.R247W on NM_020465.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/301 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as rs753085219; called by muse, mutect2
- NOP56 | c.833G>A p.R278H | Missense Mutation (SNP) | VAF 27/342 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs747781902, COSV61388773; called by muse, mutect2
- OR4X1 | c.116G>T p.G39V | Missense Mutation (SNP) | VAF 49/441 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV60723736; called by muse, mutect2, varscan2
- PALD1 | c.1453C>T p.R485W | Missense Mutation (SNP) | VAF 17/183 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.711); catalogued as rs759096960; called by muse, mutect2
- RAB19 | c.80A>G p.N27S | Missense Mutation (SNP) | VAF 43/434 reads (10%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.524); catalogued as rs367821693; called by muse, mutect2
- ZNF276 | c.922G>T p.A308S (on ENST00000443381 / NM_001113525.2; = p.A233S on NM_152287.4) | Missense Mutation (SNP) | VAF 34/301 reads (11%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as rs1169266255; called by muse, mutect2, varscan2
- ZNF668 | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 14/220 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.043); catalogued as rs1455802637; called by muse, mutect2
- CFAP92 | c.847A>G p.S283G | Missense Mutation (SNP) | VAF 33/474 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by muse, mutect2
- CLSPN | c.293C>T p.T98I | Missense Mutation (SNP) | VAF 21/225 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.134); called by muse, mutect2
- DNAH17 | c.6107G>A p.R2036K | Missense Mutation (SNP) | VAF 9/131 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KRT79 | c.824A>G p.E275G | Missense Mutation (SNP) | VAF 11/259 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2
- MED24 | c.539T>A p.I180N | Missense Mutation (SNP) | VAF 26/257 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- NEK10 | c.3296C>A p.T1099K | Missense Mutation (SNP) | VAF 36/277 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.605); called by muse, mutect2, varscan2
- NELFB | c.325T>G p.F109V | Missense Mutation (SNP) | VAF 10/232 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.607); called by muse, mutect2
- NELFB | c.327C>A p.F109L | Missense Mutation (SNP) | VAF 10/235 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.105); called by muse, mutect2
- NRXN3 | c.553G>A p.A185T (on ENST00000557594 / NM_001272020.2; = p.A817T on NM_004796.6) | Missense Mutation (SNP) | VAF 18/314 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.734); called by muse, mutect2
- PRC1 | c.500dup p.A168Gfs*3 | Frame Shift Ins (INS) | VAF 10/80 reads (13%) | called by mutect2, pindel, varscan2
- RYR3 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC12A7 | c.3239C>A p.T1080N | Missense Mutation (SNP) | VAF 30/324 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC5A2 | c.1253G>A p.G418D | Missense Mutation (SNP) | VAF 32/360 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.037); called by muse, mutect2
- STX2 | c.706G>A p.V236I | Missense Mutation (SNP) | VAF 14/179 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.591); called by muse, mutect2
- TUBG1 | c.907G>A p.V303M | Missense Mutation (SNP) | VAF 37/400 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- VWC2 | c.257G>A p.G86D | Missense Mutation (SNP) | VAF 26/206 reads (13%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- WDFY4 | c.5893_5894dup p.Q1966Pfs*50 | Frame Shift Ins (INS) | VAF 11/101 reads (11%) | called by mutect2, pindel, varscan2
- APPL2 | c.1920T>C p.Y640= | Silent (SNP) | VAF 8/179 reads (4%) | catalogued as rs1192493867; called by muse, mutect2
- CAMKK2 | c.1581C>T p.S527= | Silent (SNP) | VAF 16/161 reads (10%) | catalogued as COSV61216837; called by muse, mutect2
- CASZ1 | c.4842C>A p.I1614= | Silent (SNP) | VAF 12/194 reads (6%) | called by muse, mutect2
- CHST15 | c.1452C>T p.N484= | Silent (SNP) | VAF 12/138 reads (9%) | catalogued as rs767431529; called by muse, mutect2
- HSPA12A | c.1989G>A p.S663= | Silent (SNP) | VAF 10/139 reads (7%) | catalogued as rs1324344813, COSV65021664, COSV65022638; called by muse, mutect2
- IQCA1 | c.1653C>T p.Y551= | Silent (SNP) | VAF 41/391 reads (10%) | catalogued as rs1355386510, COSV54508271; called by muse, mutect2, varscan2
- KCNA5 | c.1407C>T p.D469= | Silent (SNP) | VAF 44/542 reads (8%) | catalogued as rs768740011, CM1212184, COSV52907745, COSV52909252; called by muse, mutect2
- NALCN | c.4551C>T p.Y1517= | Silent (SNP) | VAF 24/258 reads (9%) | catalogued as rs748173874, COSV51929902; called by muse, mutect2, varscan2
- NEK8 | c.804C>T p.D268= | Silent (SNP) | VAF 15/160 reads (9%) | catalogued as rs748341861; ClinVar: likely benign; called by muse, mutect2
- PIEZO1 | c.4599C>A p.T1533= | Silent (SNP) | VAF 24/457 reads (5%) | called by muse, mutect2
- RNF225 | c.771C>A p.P257= | Silent (SNP) | VAF 38/503 reads (8%) | called by muse, mutect2
- ZNF497 | c.513C>T p.F171= | Silent (SNP) | VAF 28/402 reads (7%) | catalogued as rs777005764; called by muse, mutect2
- AC093582.1 | n.484A>G | RNA (SNP) | VAF 10/168 reads (6%) | called by muse, mutect2
- C4orf50 | c.-1029G>A | 5'UTR (SNP) | VAF 10/149 reads (7%) | called by muse, mutect2
- OR7A2P | n.378G>A | RNA (SNP) | VAF 24/230 reads (10%) | catalogued as rs752729838; called by muse, mutect2
- RIPOR1 | c.-24+2675G>C | Intron (SNP) | VAF 9/88 reads (10%) | called by muse, mutect2, varscan2
